Somatic mutation profile of tumor specimen C3N-03093-03 (aliquot CPT0197740006) from CPTAC case C3N-03093, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G3.
Specimen C3N-03093-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a92b48c7-391d-42db-aabd-e4914cbc960b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03093-71 (Blood Derived Normal), aliquot CPT0198000002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35794c14-db05-4b5e-bedb-8674b3d1b2db

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Frame Shift Del 3, RNA 3, Intron 3, Nonsense Mutation 3, Translation Start Site 2, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028G>C p.D1010H | Missense Mutation (SNP) | VAF 44/227 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV59259218, COSV59259530, COSV59268643; called by muse, mutect2, varscan2
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 37/301 reads (12%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DISP3 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV53828740; called by muse, mutect2, varscan2
- NRP2 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 54/400 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs747836952, COSV99783181; called by muse, mutect2, varscan2
- TLR1 | c.2152C>G p.L718V | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as rs1193561345, COSV58304638, COSV58304749; called by muse, mutect2
- TRADD | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 45/366 reads (12%) | catalogued as COSV50757874; called by muse, mutect2, varscan2
- VEGFC | c.1063C>G p.P355A | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV54594281; called by muse, mutect2
- VPS13A | c.5573A>T p.K1858M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV100653096; called by muse, mutect2, varscan2
- VSIG10L | c.2312C>T p.T771M | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as rs757175251, COSV54539376; called by muse, mutect2, varscan2
- ANKS6 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ATP2B2 | c.1759A>G p.K587E (on ENST00000352432; = p.K553E on NM_001683.5) | Missense Mutation (SNP) | VAF 17/301 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CEP152 | c.3466+2T>C p.X1156_splice | Splice Site (SNP) | VAF 29/414 reads (7%) | called by muse, mutect2
- COL2A1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 34/615 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- DNAH5 | c.3496C>G p.L1166V | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.117); called by muse, mutect2
- FKBP1C | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FPGT | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- GUCA1A | c.422_429del p.S141* | Frame Shift Del (DEL) | VAF 40/419 reads (10%) | called by mutect2, pindel
- ITGA2B | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 36/664 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.078); called by muse, mutect2
- KDM2B | c.1673A>G p.D558G | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- LMLN2 | c.588del p.K197Sfs*26 | Frame Shift Del (DEL) | VAF 15/112 reads (13%) | called by mutect2, pindel, varscan2
- MAGI2 | c.4000G>A p.G1334S | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- MED17 | c.946G>T p.V316F | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- MED23 | c.1880T>A p.L627H | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2L5 | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- OR2L5 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- PAX1 | c.1059+2T>C p.X353_splice | Splice Site (SNP) | VAF 49/498 reads (10%) | called by muse, mutect2, varscan2
- PCBP4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/149 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2
- PCSK9 | c.1582C>G p.L528V | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT tolerated (0.82); PolyPhen benign (0.031); called by muse, mutect2
- PGBD1 | c.1341T>A p.N447K | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, mutect2
- PRDM9 | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 26/522 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- PTGES2 | c.271G>C p.A91P | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.708); called by muse, mutect2
- RBM10 | c.1858G>T p.E620* | Nonsense Mutation (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- SACS | c.5440G>C p.E1814Q | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- SH3GL2 | c.614T>G p.L205W | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOS1 | c.1509_1513del p.D503Efs*2 | Frame Shift Del (DEL) | VAF 47/215 reads (22%) | called by mutect2, pindel*, varscan2*
- TEX29 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/398 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- BMT2 | c.516C>G p.G172= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as COSV99774456; called by muse, mutect2, varscan2
- CYP11B2 | c.474C>T p.L158= | Silent (SNP) | VAF 62/683 reads (9%) | called by muse, mutect2
- DDX23 | c.1716C>T p.V572= | Silent (SNP) | VAF 31/630 reads (5%) | called by muse, mutect2
- DOCK3 | c.4615C>T p.L1539= | Silent (SNP) | VAF 15/259 reads (6%) | called by muse, mutect2
- EEF2K | c.1557G>T p.G519= | Silent (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- FCRL5 | c.1395C>T p.S465= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs926826526, COSV62521968; called by muse, mutect2
- IQCN | c.2199G>C p.A733= | Silent (SNP) | VAF 50/281 reads (18%) | called by muse, mutect2, varscan2
- PQBP1 | c.405C>T p.H135= | Silent (SNP) | VAF 20/423 reads (5%) | catalogued as COSV54431126; called by muse, mutect2
- PTPRO | c.1866C>T p.D622= | Silent (SNP) | VAF 22/294 reads (7%) | catalogued as COSV99841234; called by muse, mutect2
- WSCD1 | c.1035C>T p.F345= | Silent (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2, varscan2
- AF186192.2 | n.71-1010G>T | Intron (SNP) | VAF 73/585 reads (12%) | called by muse, mutect2, varscan2
- COL6A4P1 | n.218C>A | RNA (SNP) | VAF 34/497 reads (7%) | called by muse, mutect2
- CYP2G1P | n.1714C>G | RNA (SNP) | VAF 36/227 reads (16%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1511C>G | RNA (SNP) | VAF 42/948 reads (4%) | catalogued as rs779219053; called by muse, mutect2
- KLF6 | c.*2111T>G | 3'UTR (SNP) | VAF 22/221 reads (10%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67959C>T | Intron (SNP) | VAF 8/132 reads (6%) | catalogued as rs1379697529; called by muse, mutect2
- ZNF585B | c.72+8062C>G | Intron (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
